Somatic mutation profile of tumor specimen TCGA-DR-A0ZL-01A (aliquot TCGA-DR-A0ZL-01A-11D-A10S-08) from TCGA case TCGA-DR-A0ZL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 53.1 years (19,384 days).
Specimen TCGA-DR-A0ZL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb088a69-2a93-4a02-9556-1b5dd9d29e14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DR-A0ZL-10A (Blood Derived Normal), aliquot TCGA-DR-A0ZL-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03749ee3-2015-44c6-8ce5-24873a809f44

The open-access MAF lists 68 somatic variants for this specimen: 50 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 16, Nonsense Mutation 3, RNA 1, Intron 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB1 | c.3487G>A p.A1163T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.587); catalogued as rs765408476, COSV60091250; called by muse, mutect2
- APOBEC3D | c.15C>A p.I5= | Splice Region (SNP) | VAF 14/66 reads (21%) | catalogued as COSV53326080, COSV53327854; called by muse, mutect2, varscan2
- ARHGAP21 | c.5211G>C p.M1737I | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.319); catalogued as COSV57603592; called by muse, mutect2, varscan2
- ATF7IP | c.572C>G p.S191C | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.247); catalogued as COSV53767787; called by muse, mutect2, varscan2
- CACNA1E | c.5083G>A p.G1695S | Missense Mutation (SNP) | VAF 30/321 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1160971846, COSV62381053; called by muse, mutect2
- CHDH | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs774317689, COSV59456382; called by muse, mutect2, varscan2
- COL19A1 | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV59568214, COSV59575162; called by muse, mutect2, varscan2
- COPS2 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV54644593; called by muse, mutect2, varscan2
- CPB2 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs199530853; called by muse, mutect2, varscan2
- DOCK11 | c.3388A>T p.N1130Y | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.109); catalogued as COSV52235475; called by muse, mutect2
- DYNC2I1 | c.2035T>C p.C679R | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68104037; called by muse, mutect2, varscan2
- ERP29 | c.699G>A p.M233I | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV55673440; called by muse, mutect2, varscan2
- GK | c.155G>A p.W52* | Nonsense Mutation (SNP) | VAF 19/93 reads (20%) | catalogued as COSV66734141; called by muse, mutect2, varscan2
- JMJD1C | c.6904C>T p.H2302Y | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.16); catalogued as COSV59513495; called by muse, mutect2, varscan2
- KIR3DL1 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 71/379 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV58489040; called by muse, mutect2, varscan2
- LRIT2 | c.637C>A p.Q213K | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV60560507; called by muse, mutect2, varscan2
- MARCKS | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64042668; called by mutect2, varscan2
- MNDA | c.908C>G p.A303G | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV63740219; called by muse, mutect2, varscan2
- MYH15 | c.5386G>A p.E1796K | Missense Mutation (SNP) | VAF 21/408 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56306187; called by muse, mutect2
- MYO5A | c.2809G>C p.D937H | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV62557964; called by muse, mutect2, varscan2
- NCR3 | c.412A>G p.T138A | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs752238331, COSV53000733; called by muse, mutect2, varscan2
- NPHP4 | c.2762C>T p.S921F | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as rs1242346715, COSV65393810; called by muse, mutect2, varscan2
- NR2C2AP | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1310450961, COSV57393314; called by muse, mutect2, varscan2
- OBI1 | c.2012C>G p.S671C | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.024); catalogued as rs750012541, COSV56144902; called by muse, mutect2, varscan2
- OVCH1 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55477463; called by muse, mutect2, varscan2
- PCDHGA1 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 81/239 reads (34%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.037); catalogued as COSV65295451, COSV65296149; called by muse, mutect2, varscan2
- PLEKHO2 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs376472778; called by muse, mutect2, varscan2
- PRAMEF1 | c.1347G>T p.R449S | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.1); catalogued as rs775206611, COSV60007243; called by muse, mutect2, varscan2
- PTCHD3 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.56); catalogued as rs147881350; called by muse, mutect2, varscan2
- RBM25 | c.821G>C p.R274T | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV56198985; called by muse, mutect2, varscan2
- RTL9 | c.2933C>T p.P978L | Missense Mutation (SNP) | VAF 97/369 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); catalogued as rs146399635, COSV71825450; called by muse, mutect2, varscan2
- SARM1 | c.2045A>T p.K682M | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV50229309, COSV50229495; called by muse, mutect2
- SHROOM4 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs919133810, COSV56786243; called by mutect2, varscan2
- SIK2 | c.498C>G p.F166L | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as COSV59250949; called by muse, mutect2, varscan2
- SLC7A14 | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV51579399; called by muse, mutect2, varscan2
- SNRNP27 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs143382169, COSV54911227; called by muse, mutect2, varscan2
- SPATA31D1 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV61192738; called by muse, mutect2, varscan2
- SVIP | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as COSV62602950; called by muse, mutect2, varscan2
- TAT | c.744G>C p.E248D | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63532466; called by muse, mutect2, varscan2
- TEX10 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1327170230, COSV66514742; called by muse, mutect2, varscan2
- TIE1 | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.98); catalogued as rs933894938, COSV65248899; called by muse, mutect2, varscan2
- TTN | c.93182C>T p.P31061L (on ENST00000591111; = p.P23637L on NM_003319.4) | Missense Mutation (SNP) | VAF 24/131 reads (18%) | PolyPhen probably damaging (0.999); catalogued as CD143094, COSV59939893; called by muse, mutect2, varscan2
- WAC | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); catalogued as COSV61567109; called by muse, mutect2, varscan2
- ZIC1 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV51551760, COSV51556941; called by muse, mutect2, varscan2
- ZIC3 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 29/114 reads (25%) | catalogued as COSV54972973; called by muse, mutect2, varscan2
- ZNF175 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs376635595, COSV51794442; called by muse, mutect2, varscan2
- ZNF830 | c.223C>T p.H75Y | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV58488260; called by muse, mutect2, varscan2
- ZSWIM4 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.722); catalogued as rs1344452187, COSV54320081, COSV54320967; called by muse, mutect2, varscan2
- HEATR9 | c.1279G>A p.G427S | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.338); called by muse, mutect2
- OTOGL | c.2295_2298del p.S766Pfs*63 (on ENST00000547103; = p.S757Pfs*63 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- ADD3 | c.987A>G p.G329= | Silent (SNP) | VAF 36/158 reads (23%) | catalogued as COSV53321172; called by muse, mutect2, varscan2
- ALX3 | c.861G>C p.V287= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs777356167; called by muse, varscan2
- DAPK3 | c.375C>T p.D125= | Silent (SNP) | VAF 34/258 reads (13%) | catalogued as rs763048239, COSV56662481; called by muse, mutect2, varscan2
- FBXL7 | c.990C>T p.S330= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV61642958; called by muse, mutect2
- GLIS2 | c.258A>G p.P86= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs1415363476, COSV52109701; called by muse, mutect2, varscan2
- H2AC11 | c.381G>T p.A127= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as rs751986308, COSV60361840; called by muse, mutect2, varscan2
- H4C13 | c.183G>A p.V61= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as rs777439995, COSV60693419; called by muse, mutect2, varscan2
- HTR2C | c.384C>T p.P128= | Silent (SNP) | VAF 24/340 reads (7%) | catalogued as rs782209211, COSV52204342; called by muse, mutect2
- NALCN | c.3909C>T p.G1303= | Silent (SNP) | VAF 56/185 reads (30%) | catalogued as rs143218624, COSV51923855; called by muse, mutect2, varscan2
- PCDHA9 | c.2082G>T p.V694= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV65324300; called by muse, mutect2, varscan2
- PFKM | c.711C>T p.D237= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as rs768094970, COSV56656427; called by muse, mutect2, varscan2
- SORCS1 | c.2037A>G p.R679= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV53849430; called by muse, mutect2
- SOX14 | c.366C>T p.P122= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs755327493, COSV100048338, COSV60163422; called by muse, mutect2, varscan2
- TEX2 | c.1204C>T p.L402= | Silent (SNP) | VAF 38/178 reads (21%) | catalogued as COSV51978628; called by muse, mutect2, varscan2
- TRPC3 | c.1278G>T p.V426= (on ENST00000379645 / NM_001366479.2; = p.V353= on NM_003305.2) | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV53373106, COSV53375091; called by muse, mutect2, varscan2
- ZNF91 | c.1242T>A p.A414= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV56081994; called by muse, mutect2
- MGAM | c.4618+1955C>A | Intron (SNP) | VAF 14/200 reads (7%) | catalogued as COSV101527707, COSV72074427; called by muse, mutect2
- RPS26P15 | n.325C>T | RNA (SNP) | VAF 20/134 reads (15%) | catalogued as rs762423998; called by muse, mutect2, varscan2
